Somatic mutation profile of tumor specimen 0E2CNV from CCDI case PBCUYP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0E2CNV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c69e4354-2c20-457d-b359-81419e7ff22d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E18I2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a9d33b28-3c1f-43bc-8d99-43bf598582dd

The open-access MAF lists 5 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, Missense Mutation 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OSBPL6 | c.971C>A p.T324K | Missense Mutation (SNP) | VAF 178/896 reads (20%) | SIFT tolerated (0.9); PolyPhen benign (0.01); called by mutect2, varscan2
- ZMAT1 | c.506-2A>T p.X169_splice | Splice Site (SNP) | VAF 113/619 reads (18%) | called by muse, mutect2, varscan2
- GATA4 | c.843G>T p.L281= | Silent (SNP) | VAF 118/488 reads (24%) | catalogued as COSV58735920; called by mutect2, varscan2
- HLX | c.15G>A p.G5= | Silent (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- C2 | c.989-96T>A | Intron (SNP) | VAF 4/36 reads (11%) | called by muse, varscan2
